Somatic mutation profile of tumor specimen TCGA-CZ-5468-01A (aliquot TCGA-CZ-5468-01A-01D-1501-10) from TCGA case TCGA-CZ-5468, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 84.1 years (30,729 days).
Specimen TCGA-CZ-5468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbe14fe1-b4c9-48e1-9291-214092f90c49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5468-11A (Solid Tissue Normal), aliquot TCGA-CZ-5468-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5629928-3db6-43c9-80f1-2d8de995b350

The open-access MAF lists 131 somatic variants for this specimen: 101 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 27, Frame Shift Del 5, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 2, Intron 1, In Frame Del 1, 5'Flank 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 93/308 reads (30%) | catalogued as rs62646861, CM992297, COSV64673233; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5539T>G p.C1847G (on ENST00000272895 / NM_173076.3; = p.C1529G on NM_015657.3) | Missense Mutation (SNP) | VAF 223/535 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55963049; called by muse, mutect2, varscan2
- ABCA4 | c.6312G>T p.Q2104H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV64674436; called by muse, mutect2, varscan2
- ABHD12 | c.1103T>G p.L368R | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs748330820, COSV53819657; called by muse, mutect2
- ABHD18 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 152/487 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV66294100; called by muse, mutect2, varscan2
- AC098582.1 | c.2534T>A p.F845Y | Missense Mutation (SNP) | VAF 160/445 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52021247, COSV52023967; called by muse, mutect2, varscan2
- AGO2 | c.1450C>G p.P484A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV55048577; called by muse, mutect2, varscan2
- AGO2 | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV55048595; called by muse, mutect2, varscan2
- ANKRD55 | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 170/436 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770663123, COSV61947501; called by muse, varscan2
- APC | c.5650G>T p.A1884S | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57351964; called by muse, mutect2, varscan2
- ASB15 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV51926778; called by muse, mutect2, varscan2
- ASCC3 | c.1091T>A p.L364H | Missense Mutation (SNP) | VAF 336/1037 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as COSV61229911; called by muse, mutect2, varscan2
- B3GNT2 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57344952; called by muse, mutect2
- BCHE | c.1648T>A p.W550R | Missense Mutation (SNP) | VAF 86/658 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52257961, COSV52258796; called by muse, mutect2, varscan2
- BRPF1 | c.2806A>C p.M936L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100121242; called by muse, varscan2
- CADPS | c.3995G>T p.S1332I | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV51885311; called by muse, mutect2, varscan2
- CAND2 | c.1251G>T p.M417I (on ENST00000456430 / NM_001162499.2; = p.M324I on NM_012298.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55991095; called by muse, mutect2, varscan2
- CARNMT1 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.13); catalogued as COSV65190467; called by muse, mutect2, varscan2
- CCDC136 | c.273G>A p.G91= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52800746; called by mutect2, varscan2
- CCNY | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV55186148; called by muse, mutect2, varscan2
- CDC42BPA | c.2247A>G p.E749= | Splice Region (SNP) | VAF 79/209 reads (38%) | catalogued as COSV62013259; called by muse, mutect2, varscan2
- CDH7 | c.1814T>A p.L605H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59887986; called by muse, mutect2, varscan2
- CDK12 | c.1946T>G p.L649R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV71001190, COSV71001888; called by muse, mutect2
- CDK13 | c.4385A>G p.Y1462C | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51701728; called by muse, mutect2, varscan2
- CFAP57 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs781631334, COSV65264705; called by muse, mutect2, varscan2
- CLCN7 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781351932, COSV51971220; called by muse, mutect2, varscan2
- CLIP1 | c.1477A>G p.K493E (on ENST00000620786 / NM_001247997.1; = p.K482E on NM_002956.2) | Missense Mutation (SNP) | VAF 239/417 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56803351; called by muse, mutect2, varscan2
- CNPY4 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV53542664; called by muse, mutect2, varscan2
- CNTNAP4 | c.1583T>A p.L528Q | Missense Mutation (SNP) | VAF 86/498 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56685699; called by muse, mutect2, varscan2
- COPS5 | c.587del p.P196Lfs*16 | Frame Shift Del (DEL) | VAF 59/266 reads (22%) | catalogued as COSV63474939; called by pindel, varscan2
- CPZ | c.1192G>A p.E398K (on ENST00000360986 / NM_001014447.3; = p.E387K on NM_003652.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as rs1560296190, COSV59923651; called by mutect2, varscan2
- DENND4B | c.1357T>A p.Y453N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63409933; called by muse, mutect2, varscan2
- DIP2C | c.2542C>A p.P848T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV55162727; called by muse, mutect2, varscan2
- DOCK10 | c.4199C>A p.S1400Y | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV51417893; called by muse, mutect2, varscan2
- DRD1 | c.877T>A p.C293S | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67104791; called by muse, mutect2, varscan2
- DSCAM | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 158/353 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs200160585, COSV68643333; called by muse, mutect2, varscan2
- ECT2 | c.1739C>G p.A580G (on ENST00000392692 / NM_001349098.2; = p.A549G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV51690052; called by muse, mutect2, varscan2
- ENTHD1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57321464; called by muse, mutect2, varscan2
- FHL2 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59079772; called by muse, mutect2
- GAB2 | c.1786G>A p.V596I (on ENST00000361507 / NM_080491.3; = p.V558I on NM_012296.3) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs145573768; called by muse, mutect2, varscan2
- GCC2 | c.3471G>C p.L1157F | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59177199; called by muse, mutect2, varscan2
- HLF | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs752578837, COSV56830490; called by muse, mutect2, varscan2
- INPP4A | c.605T>G p.L202W | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV50797947; called by muse, mutect2, varscan2
- IST1 | c.365G>A p.R122Q (on ENST00000535424 / NM_001270976.1; = p.R109Q on NM_014761.4) | Missense Mutation (SNP) | VAF 75/399 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs546798417, COSV61708753, COSV61711018; called by muse, mutect2, varscan2
- KDM5B | c.1216G>T p.V406F | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52509049; called by muse, mutect2, varscan2
- KLHL17 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.301); catalogued as COSV58532247; called by muse, mutect2, varscan2
- KNL1 | c.6563-2A>T p.X2188_splice (on ENST00000346991 / NM_170589.5; = p.X2162_splice on NM_144508.5) | Splice Site (SNP) | VAF 22/62 reads (35%) | catalogued as COSV61156154; called by muse, mutect2, varscan2
- LIPI | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60712600; called by muse, mutect2, varscan2
- LXN | c.338T>C p.M113T | Missense Mutation (SNP) | VAF 202/635 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.103); catalogued as COSV51833341; called by muse, mutect2, varscan2
- M1AP | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51845580; called by muse, mutect2, varscan2
- MAN2C1 | c.3031C>A p.H1011N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as COSV51230503; called by muse, mutect2, varscan2
- MARCHF10 | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV60888200; called by muse, mutect2, varscan2
- MARS1 | c.89T>A p.I30N | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV56255730; called by muse, mutect2, varscan2
- MPO | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966981051, COSV51858428, COSV51859846; called by muse, varscan2
- MRGPRX3 | c.821T>A p.F274Y | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66934154; called by muse, mutect2, varscan2
- MSS51 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV55019539; called by muse, mutect2, varscan2
- MXRA5 | c.5989C>T p.P1997S | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.472); catalogued as rs755226418, COSV54238902; called by muse, mutect2, varscan2
- MYH11 | c.3507G>C p.R1169S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55556932; called by muse, mutect2
- NECTIN2 | c.1589T>C p.F530S | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV52977996; called by muse, mutect2, varscan2
- NOL6 | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53042781; called by muse, mutect2, varscan2
- NRXN1 | c.2482C>A p.Q828K | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.038); catalogued as COSV58462041; called by muse, mutect2, varscan2
- PHF20 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59186703; called by muse, mutect2
- PHF3 | c.1466A>T p.K489I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV50322188; called by muse, mutect2, varscan2
- PSG8 | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1344607151, COSV60612730; called by muse, mutect2, varscan2
- PXDN | c.4177C>G p.Q1393E | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs776635258, COSV53237350; called by muse, mutect2, varscan2
- PYGO1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV57348259; called by muse, varscan2
- RAB26 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52954780; called by muse, mutect2, varscan2
- RBM27 | c.2208G>C p.Q736H | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.271); catalogued as COSV54590956; called by muse, mutect2, varscan2
- RELN | c.1673del p.F558Sfs*14 | Frame Shift Del (DEL) | VAF 100/538 reads (19%) | catalogued as COSV58990535; called by mutect2, pindel, varscan2
- RNF25 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs766021702, COSV55308071; called by muse, mutect2
- RNF26 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV60990755; called by muse, mutect2, varscan2
- RPRD2 | c.4205C>A p.S1402* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV64821242; called by muse, mutect2, varscan2
- SCAF11 | c.1634A>G p.H545R | Missense Mutation (SNP) | VAF 100/176 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs1026734107, COSV65477158; called by muse, mutect2
- SEC24A | c.716T>A p.F239Y | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.062); catalogued as COSV59747873; called by muse, mutect2, varscan2
- SGPP1 | c.1286T>G p.F429C | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV55975704; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 46/178 reads (26%) | PolyPhen benign (0.057); catalogued as COSV99833363; called by muse, mutect2
- TLN2 | c.6397G>A p.V2133I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779433875, COSV60890989; called by muse, mutect2, varscan2
- TMC5 | c.959T>G p.V320G | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66866741; called by muse, mutect2, varscan2
- TMX4 | c.708T>A p.H236Q | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55681104; called by muse, mutect2, varscan2
- TOE1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV59153420; called by muse, mutect2, varscan2
- TRMT9B | c.1354G>C p.G452R | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV71600459; called by muse, mutect2
- TRPC7 | c.2269C>G p.R757G | Missense Mutation (SNP) | VAF 172/451 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV61459235; called by muse, mutect2, varscan2
- TYRP1 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs775038224, COSV66358052; called by muse, mutect2
- UBLCP1 | c.336A>T p.E112D | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.585); catalogued as COSV57143667; called by muse, mutect2, varscan2
- UBN1 | c.2623A>G p.T875A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.089); catalogued as COSV52169132; called by muse, mutect2, varscan2
- UBN2 | c.1791A>G p.I597M | Missense Mutation (SNP) | VAF 464/942 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV56032051; called by muse, mutect2, varscan2
- UBOX5 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53906683; called by muse, mutect2, varscan2
- USP34 | c.9319A>G p.N3107D | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV68402434; called by muse, mutect2, varscan2
- ZBBX | c.1939A>C p.S647R | Missense Mutation (SNP) | VAF 133/382 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV56792151; called by muse, mutect2, varscan2
- ZFAT | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 56/558 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV64740292; called by muse, mutect2
- ZHX1 | c.2408T>A p.L803H | Missense Mutation (SNP) | VAF 153/446 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52877307; called by muse, mutect2, varscan2
- ZNF600 | c.1796G>C p.R599T | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.105); catalogued as COSV57742494, COSV57743218; called by muse, mutect2, varscan2
- ZNF804B | c.3817G>A p.A1273T | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.105); catalogued as rs1232041906, COSV60832713; called by muse, mutect2
- ZPLD1 | c.668A>C p.N223T (on ENST00000466937 / NM_001329788.1; = p.N239T on NM_175056.2) | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60354277; called by muse, mutect2, varscan2
- MTUS1 | c.526_528del p.H176del | In Frame Del (DEL) | VAF 10/63 reads (16%) | called by pindel, varscan2
- MUTYH | c.1500del p.T501Pfs*67 | Frame Shift Del (DEL) | VAF 47/161 reads (29%) | called by mutect2, pindel, varscan2
- PCLO | c.3805del p.V1269Yfs*49 | Frame Shift Del (DEL) | VAF 430/1437 reads (30%) | called by mutect2, pindel, varscan2
- REV3L | c.4673dup p.N1558Kfs*2 | Frame Shift Ins (INS) | VAF 190/607 reads (31%) | called by mutect2, pindel, varscan2
- ROCK2 | c.435_441del p.F146Ifs*21 | Frame Shift Del (DEL) | VAF 87/314 reads (28%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2
- UGT1A8 | c.405dup p.Y136Ifs*8 | Frame Shift Ins (INS) | VAF 156/462 reads (34%) | called by mutect2, pindel, varscan2
- ACSL1 | c.894A>G p.S298= | Silent (SNP) | VAF 103/311 reads (33%) | catalogued as COSV55663584; called by muse, mutect2, varscan2
- CALD1 | c.744A>T p.S248= | Silent (SNP) | VAF 23/319 reads (7%) | catalogued as COSV62648977; called by muse, mutect2
- CCDC97 | c.870C>T p.H290= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs992951454, COSV54190747; called by muse, mutect2
- CFHR3 | c.978C>T p.Y326= | Silent (SNP) | VAF 56/359 reads (16%) | catalogued as rs758807242, COSV66402453; called by muse, mutect2, varscan2
- GBA | c.1401T>A p.P467= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100516377, COSV59170093; called by muse, mutect2, varscan2
- IGSF9B | c.3942G>A p.L1314= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV58069072; called by mutect2, varscan2
- KANSL3 | c.451C>A p.R151= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV62618508; called by muse, mutect2, varscan2
- KIN | c.102G>A p.Q34= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs762954328, COSV59622003; called by muse, mutect2, varscan2
- KRT2 | c.816C>T p.I272= | Silent (SNP) | VAF 202/737 reads (27%) | catalogued as COSV59010968; called by muse, mutect2, varscan2
- MARCHF10 | c.789G>T p.G263= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV60888190; called by muse, mutect2, varscan2
- MBD1 | c.1683A>T p.P561= (on ENST00000269468 / NM_001323950.1; = p.P459= on NM_002384.2) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV54002899; called by muse, mutect2, varscan2
- OLFM4 | c.1495C>T p.L499= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV54578211; called by muse, mutect2, varscan2
- PSMC2 | c.1248C>T p.V416= | Silent (SNP) | VAF 85/474 reads (18%) | catalogued as COSV53007840; called by muse, mutect2, varscan2
- RHBDF1 | c.1986G>A p.L662= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51956139; called by muse, mutect2, varscan2
- RNF213 | c.9609A>G p.A3203= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as COSV60400316; called by muse, mutect2
- RWDD2B | c.450T>C p.C150= | Silent (SNP) | VAF 102/186 reads (55%) | catalogued as COSV54501750; called by muse, mutect2, varscan2
- SDK2 | c.1641C>T p.R547= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV66188399; called by muse, mutect2, varscan2
- SYMPK | c.3291C>A p.I1097= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV55572978; called by muse, mutect2, varscan2
- TMIGD3 | c.387C>G p.A129= (on ENST00000369717 / NM_001081976.2; = p.A210= on NM_020683.7) | Silent (SNP) | VAF 74/414 reads (18%) | catalogued as COSV63163491, COSV63163548; called by muse, mutect2, varscan2
- TNR | c.1743C>T p.N581= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs758748473, COSV54889946, COSV54891930; called by muse, mutect2, varscan2
- TRAPPC8 | c.4168C>T p.L1390= | Silent (SNP) | VAF 56/243 reads (23%) | catalogued as COSV51972662; called by muse, mutect2, varscan2
- UBR4 | c.8001C>T p.Y2667= | Silent (SNP) | VAF 51/294 reads (17%) | catalogued as COSV64391953; called by muse, mutect2, varscan2
- VCAN | c.1548T>G p.T516= | Silent (SNP) | VAF 77/268 reads (29%) | catalogued as COSV54107795; called by muse, mutect2
- VPS37C | c.868A>C p.R290= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV57109058; called by muse, mutect2
- WDR33 | c.1899A>T p.G633= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV59250625; called by muse, mutect2, varscan2
- XYLT1 | c.2595T>C p.N865= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV54487126; called by muse, mutect2
- ZNF609 | c.3162C>A p.P1054= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs779472977, COSV58585083; called by muse, mutect2, varscan2
- BABAM2 | c.1088+11630C>T | Intron (SNP) | VAF 39/324 reads (12%) | catalogued as COSV59625345; called by muse, mutect2, varscan2
- OR51T1 | chr11:4881868 del C | 5'Flank (DEL) | VAF 51/204 reads (25%) | catalogued as COSV100434513; called by mutect2, pindel, varscan2
- ST3GAL4 | c.*2C>A | 3'UTR (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99917445; called by muse, mutect2, varscan2
